Somatic mutation profile of tumor specimen TCGA-DJ-A1QQ-01A (aliquot TCGA-DJ-A1QQ-01A-11D-A14W-08) from TCGA case TCGA-DJ-A1QQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 43.7 years (15,949 days).
Specimen TCGA-DJ-A1QQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2c7d641-3a58-4ce4-8587-343b24c63c0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A1QQ-10A (Blood Derived Normal), aliquot TCGA-DJ-A1QQ-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/303a8a42-5741-464a-b3f2-f95806ba6e34

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAMTS19 | c.1519G>C p.D507H | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); catalogued as COSV50733674; called by muse, mutect2
- ALS2CL | c.906G>C p.Q302H | Missense Mutation (SNP) | VAF 12/257 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV59670371; called by muse, mutect2
- CANX | c.1452G>T p.W484C | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56002875; called by muse, varscan2
- MMP3 | c.628A>T p.T210S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as rs1358457873, COSV55405301; called by muse, mutect2, varscan2
- MYO9A | c.4263T>A p.F1421L | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV61848126; called by muse, mutect2, varscan2
- PPL | c.3805A>G p.I1269V | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV52166148; called by muse, mutect2
- VPS52 | c.1310G>A p.C437Y | Missense Mutation (SNP) | VAF 11/249 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV71403407; called by muse, mutect2
- ZC3H11A | c.1702C>G p.Q568E | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV59744747; called by muse, mutect2, varscan2
- CACNB1 | c.1224T>C p.Y408= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV59998179; called by muse, mutect2, varscan2
- OR7G3 | c.705T>C p.Y235= | Silent (SNP) | VAF 30/189 reads (16%) | catalogued as COSV59640004; called by muse, mutect2, varscan2
- PKD1L2 | c.1206C>T p.G402= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV61412338; called by muse, mutect2, varscan2
- SCN5A | c.720G>A p.V240= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV61117654; called by muse, mutect2, varscan2
